Gene-level copy-number profile of tumor specimen HCM-SANG-0286-C20-08A-01D-A80T-32 from HCMI case HCM-SANG-0286-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0286-C20-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8fc3031-c8d8-4f31-8dba-ff7ba5852bdf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0286-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/5475feb8-e963-474d-b24f-258d70fe3dd1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 552; copy number 1: 79; copy number 2: 413; copy number 3: 3,483; copy number 4: 25,931; copy number 5: 11,134; copy number 6: 11,663; copy number 7: 3,582; copy number 8: 1,902; copy number 9: 153; copy number 10: 8; copy number 11: 1; copy number 14: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr15:30,083,053–30,600,647, 33 genes: GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 164 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,019,340–177,628,287, 10 genes, copy number 9: TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, RN7SKP52, AC026355.3, AC026355.1.
- chr5:126,737,438–126,776,486, 3 genes, copy number 9: HSPE1P10, LMNB1-DT, RNU6-752P.
- chr7:57,485,166–57,485,895, 1 gene, copy number 15: AC092175.1.
- chr7:107,168,961–107,202,522, 2 genes, copy number 9 (within-gene range 8–9): HBP1, AC004492.1.
- chr14:18,692,032–18,692,408, 1 gene, copy number 14: RPL22P20.
- chr16:74,367,462–74,392,080, 2 genes, copy number 9 (within-gene range 4–9): AC009053.2, NPIPB15.
- chr20:5,532,878–5,864,395, 5 genes, copy number 9: RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1.
- chr20:31,605,283–31,808,749, 8 genes, copy number 10: ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1.
- chr20:33,912,323–37,179,588, 114 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr20:52,972,358–53,875,557, 16 genes, copy number 9: TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1.
- chr21:10,649,400–10,649,835, 1 gene, copy number 11: IGHV1OR21-1.
- chr21:46,286,342–46,297,751, 1 gene, copy number 9: YBEY.

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
